Somatic mutation profile of tumor specimen TCGA-61-1904-01A (aliquot TCGA-61-1904-01A-01W-0639-09) from TCGA case TCGA-61-1904, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.3 years (22,009 days).
Specimen TCGA-61-1904-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83b4f53-20f6-4248-b532-b292e1defa56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1904-11A (Solid Tissue Normal), aliquot TCGA-61-1904-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ea129c3-1b75-4447-87a3-38371dcb959f

The open-access MAF lists 88 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 21, Frame Shift Del 10, Nonsense Mutation 5, Splice Site 4, In Frame Del 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 89/105 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185760690; called by muse, mutect2, varscan2
- ACRBP | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 156/325 reads (48%) | catalogued as COSV57524217; called by muse, mutect2, varscan2
- ALDH1L1 | c.295dup p.R99Pfs*14 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs755422577; called by pindel, varscan2
- ATL3 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 12/177 reads (7%) | catalogued as rs772705343, COSV100219832; called by muse, mutect2
- CDC20B | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 132/164 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs755234113, COSV57050229, COSV57053402; called by muse, varscan2
- CHD4 | c.2954A>G p.N985S (on ENST00000357008 / NM_001363606.2; = p.N998S on NM_001273.5) | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.554); catalogued as rs758014481, COSV100537858; called by muse, mutect2
- DACT1 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV60021285; called by muse, mutect2
- DIAPH2 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as COSV61273289; called by muse, mutect2, varscan2
- DNAH9 | c.11376C>A p.F3792L | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV52354057; called by muse, mutect2
- ENTHD1 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV57321190; called by muse, mutect2, varscan2
- FAM131B | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV68126269; called by muse, varscan2
- FLNC | c.5339C>A p.S1780Y | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV57950783, COSV57957314; called by muse, varscan2
- FOXO1 | c.869C>A p.S290* | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | catalogued as COSV65427129; called by muse, mutect2, varscan2
- FTH1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV56445519; called by muse, mutect2, varscan2
- GH1 | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 20/93 reads (22%) | catalogued as COSV60111130; called by muse, mutect2, varscan2
- HAS1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs756514995, COSV55787943, COSV99708621; called by muse, mutect2, varscan2
- HMCN1 | c.3481C>G p.Q1161E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV54907308, COSV99633548; called by muse, mutect2, varscan2
- KLHDC7A | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68770037; called by muse, mutect2, varscan2
- LAMA1 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV67538666, COSV67546172; called by muse, mutect2, varscan2
- LRCH4 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV59643511; called by muse, mutect2, varscan2
- MAP4K4 | c.2683C>T p.P895S (on ENST00000347699 / NM_001242559.2; = p.P813S on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.844); catalogued as COSV56332746; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3395G>A p.S1132N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51601094; called by muse, mutect2, varscan2
- MORC1 | c.2579A>C p.K860T | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV51721772; called by muse, mutect2, varscan2
- OR2T33 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs764655627, COSV100532385, COSV58815735, COSV58817782; called by muse, varscan2
- OTOF | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV55505719, COSV99064329; called by muse, mutect2
- PAK1 | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 37/347 reads (11%) | catalogued as COSV53695373, COSV53697384; called by muse, mutect2, varscan2
- PDE3A | c.3208A>G p.K1070E | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV100762068; called by muse, mutect2
- PDS5B | c.1879A>G p.K627E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.221); catalogued as COSV59728595; called by muse, mutect2, varscan2
- POLR3B | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57279970; called by muse, varscan2
- POM121 | c.1495G>A p.G499S (on ENST00000434423; = p.G234S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/491 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV57517246; called by muse, mutect2, varscan2
- PRPF38A | c.160T>G p.L54V | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57122638; called by muse, mutect2, varscan2
- RBPJL | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59212802, COSV59213466; called by muse, mutect2, varscan2
- RIMKLA | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.803); catalogued as rs369934711; called by mutect2, varscan2
- RUFY2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99769228; called by muse, varscan2
- SLC26A3 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758633508, COSV60639959; called by muse, mutect2, varscan2
- SMYD2 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as COSV100873193; called by muse, mutect2
- SPTBN1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61695252; called by muse, varscan2
- TAX1BP1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 12/170 reads (7%) | catalogued as COSV99604406; called by muse, mutect2
- TCERG1L | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs528779135, COSV100894129, COSV64049729; called by muse, mutect2, varscan2
- TRIM17 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54382762; called by muse, mutect2, varscan2
- UNC13C | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 59/131 reads (45%) | catalogued as rs1337986902, COSV52882831; called by muse, mutect2, varscan2
- WNT9A | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs776263074, COSV55293817, COSV99688378; called by muse, mutect2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF197 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100482070; called by muse, mutect2
- ZNF33A | c.1148C>T p.P383L (on ENST00000458705 / NM_006974.3; = p.P384L on NM_006954.2) | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1481327959, COSV56725579; called by muse, mutect2, varscan2
- ANXA6 | c.176G>A p.C59Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.518); called by muse, varscan2
- BCR | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by mutect2, varscan2
- BNIP5 | c.1870_1871del p.G624Pfs*23 | Frame Shift Del (DEL) | VAF 78/149 reads (52%) | called by mutect2, pindel
- CDH1 | c.1712-2_1712-1del p.X571_splice | Splice Site (DEL) | VAF 22/116 reads (19%) | called by mutect2, pindel, varscan2
- CGGBP1 | c.359_360del p.K120Sfs*2 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- COX10 | c.37_38del p.L13Dfs*12 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- CTCFL | c.388_389del p.L130Afs*7 | Frame Shift Del (DEL) | VAF 15/26 reads (58%) | called by mutect2, varscan2
- DIABLO | c.460del p.R154Gfs*40 (on ENST00000443649 / NM_001278303.1; = p.R227Gfs*40 on NM_019887.6) | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by pindel, varscan2
- L3MBTL2 | c.1579_1581del p.F527del | In Frame Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- PAX7 | c.875T>C p.F292S | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by mutect2, varscan2
- PDE2A | c.2610_2615+14del p.X870_splice | Splice Site (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- RBM18 | c.236_237del p.K79Tfs*33 | Frame Shift Del (DEL) | VAF 65/134 reads (49%) | called by mutect2, pindel, varscan2
- RRM2B | c.598_599del p.G200Ifs*22 | Frame Shift Del (DEL) | VAF 79/391 reads (20%) | called by mutect2, pindel, varscan2
- SOX5 | c.118_121del p.E40Kfs*16 | Frame Shift Del (DEL) | VAF 49/335 reads (15%) | called by mutect2, pindel, varscan2
- TDP1 | c.964_1002del p.D322_S334del | In Frame Del (DEL) | VAF 16/162 reads (10%) | called by mutect2, pindel
- TRMT9B | c.683del p.N228Ifs*16 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- TTN | c.99130G>A p.E33044K (on ENST00000591111; = p.E25620K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/265 reads (4%) | PolyPhen possibly damaging (0.737); called by muse, mutect2
- WDR6 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by mutect2, varscan2
- WDR62 | c.2053G>A p.G685S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFPM2 | c.3128del p.I1043Kfs*2 | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | called by mutect2, pindel
- AASS | c.585G>A p.V195= | Silent (SNP) | VAF 12/349 reads (3%) | catalogued as COSV62789846; called by muse, mutect2
- ADGRB1 | c.2571G>C p.V857= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV60097921; called by muse, mutect2
- AVP | c.78G>A p.P26= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs537943771, COSV66671790; called by muse, mutect2, varscan2
- BDP1 | c.5745T>G p.S1915= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV62431954; called by muse, varscan2
- COL2A1 | c.858C>T p.V286= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV100476302; called by muse, mutect2
- COL5A1 | c.1476C>T p.V492= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs141093527; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELF4 | c.672C>T p.T224= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs774807847; called by muse, mutect2, varscan2
- EPHA8 | c.1032G>A p.V344= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV51272149; called by muse, mutect2, varscan2
- FCGBP | c.594C>T p.Y198= | Silent (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- INTS2 | c.2085G>A p.Q695= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- LRRK2 | c.5856G>A p.K1952= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as COSV54156055; called by muse, mutect2, varscan2
- MUC3A | c.354C>T p.T118= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs752287360, COSV100114511, COSV100115157; called by muse, mutect2, varscan2
- NOL9 | c.1779G>T p.G593= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100891465, COSV66626209; called by muse, mutect2, varscan2
- PAX7 | c.876C>T p.F292= | Silent (SNP) | VAF 33/58 reads (57%) | called by mutect2, varscan2
- PCDHGC3 | c.1317C>G p.A439= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV99339740; called by mutect2, varscan2
- PLEK | c.483C>A p.V161= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV52252259; called by muse, mutect2, varscan2
- SHC3 | c.636C>T p.I212= | Silent (SNP) | VAF 320/368 reads (87%) | catalogued as COSV65438904; called by muse, mutect2, varscan2
- SIGLEC14 | c.1044G>A p.E348= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- SLC24A4 | c.741C>T p.Y247= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV54114482; called by muse, mutect2, varscan2
- SYMPK | c.579C>T p.T193= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV55612505, COSV55615144; called by muse, varscan2
- ZAN | c.5344C>T p.L1782= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs200480489, COSV61810223; called by muse, mutect2, varscan2
- ZNF254 | c.-1G>A | 5'UTR (SNP) | VAF 13/158 reads (8%) | catalogued as COSV100298175; called by muse, mutect2
